Somatic mutation profile of tumor specimen TCGA-D7-6522-01A (aliquot TCGA-D7-6522-01A-11D-1800-08) from TCGA case TCGA-D7-6522, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 58.8 years (21,465 days).
Specimen TCGA-D7-6522-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56715851-54ee-4c48-add4-beb3407a8e00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6522-10A (Blood Derived Normal), aliquot TCGA-D7-6522-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e933aab-3629-46bd-80ce-3194f385d48f

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Intron 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1320+1G>T p.X440_splice | Splice Site (SNP) | VAF 17/344 reads (5%) | hotspot (GDC flag); catalogued as COSV55727403, COSV55730311, COSV55730426, COSV55740321; called by muse, mutect2
- RHOA | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 11/242 reads (5%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1057519954, COSV69041523, COSV69041892, COSV69042190; ClinVar: likely pathogenic; called by muse, mutect2
- ACAN | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.522); catalogued as rs1177970558, COSV61365641; called by muse, mutect2
- BTD | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV57729968; called by muse, mutect2
- CIART | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782449723, COSV51745318; called by muse, mutect2
- DSC1 | c.2645C>A p.P882H | Missense Mutation (SNP) | VAF 7/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57144392; called by muse, mutect2
- FAM120C | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.025); catalogued as rs782041088, COSV60260993; called by muse, mutect2
- GTF3C1 | c.6120C>A p.G2040= | Splice Region (SNP) | VAF 7/75 reads (9%) | catalogued as COSV62243256; called by muse, mutect2
- IL13RA1 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as COSV65426717; called by muse, mutect2
- MSL3 | c.1538G>A p.S513N (on ENST00000312196 / NM_078629.4; = p.S347N on NM_006800.4) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.954); catalogued as rs1276484800, COSV56494833; called by muse, mutect2
- OR8J1 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs763680308, COSV57319344, COSV99073154; called by muse, mutect2
- P2RY8 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67177915; called by muse, mutect2
- PCDHB2 | c.66G>T p.L22F | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as rs1554271085, COSV52035476; called by muse, mutect2
- PDZRN4 | c.1233A>C p.Q411H (on ENST00000402685 / NM_001164595.2; = p.Q153H on NM_013377.4) | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54210219; called by muse, mutect2
- PRKG1 | c.1556G>C p.G519A | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64774830, COSV64775349; called by muse, mutect2
- PTPRZ1 | c.2918A>C p.K973T | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV66429333; called by muse, mutect2
- RASGRP3 | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67823809; called by muse, mutect2
- SAGE1 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs782012489, COSV61015793; called by muse, mutect2
- SCAF4 | c.960-1G>A p.X320_splice | Splice Site (SNP) | VAF 7/182 reads (4%) | catalogued as COSV54590250; called by muse, mutect2
- SYNE1 | c.19792C>A p.L6598M (on ENST00000367255 / NM_182961.4; = p.L6527M on NM_033071.3) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV55048017; called by muse, mutect2
- TGFBR2 | c.1325T>C p.F442S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55455566, COSV55461648; called by muse, mutect2
- C6orf201 | c.60C>T p.R20= | Silent (SNP) | VAF 13/343 reads (4%) | catalogued as COSV60987856; called by muse, mutect2
- DLGAP2 | c.1308G>C p.G436= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV70101819; called by muse, mutect2, varscan2
- GTPBP4 | c.1078C>T p.L360= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV62550321; called by muse, mutect2
- MAGEC3 | c.1023C>T p.S341= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs750027584, COSV100025774; called by muse, mutect2, varscan2
- TCTN2 | c.600G>T p.R200= | Silent (SNP) | VAF 22/202 reads (11%) | catalogued as COSV57634135; called by muse, mutect2, varscan2
- CTHRC1 | c.150+775C>T | Intron (SNP) | VAF 10/100 reads (10%) | catalogued as rs1410259360, COSV100373018; called by muse, mutect2, varscan2
- FCRL2 | c.884-37C>T | Intron (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100829960; called by muse, mutect2
